Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5978, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5978-01A (Primary Tumor).

[page 1 of 3]
DIAGNOSIS

(A) LEFT NECK DISSECTION LEVEL II:

Ten lymph nodes, negative for tumor (0/10).

(B) LEFT NECK DISSECTION LEVEL III:

Ten lymph nodes, negative for tumor (0/10).

(C) LEFT NECK DISSECTION, LEVEL IV:

METASTATIC SQUAMOUS CARCINOMA IN ONE OF TWENTY LYMPH NODES (1/20)

Extracapsular extension is not identified.

(D) RIGHT RADICAL NECK DISSECTION:

METASTATIC SQUAMOUS CARCINOMA IN THREE OF NINE LYMPH NODES IN LEVELS I AND II (3/9)

EXTRANODAL EXTENSION PRESENT

SQUAMOUS CARCINOMA IN SUBCUTANEOUS TISSUE INVOLVING LEVELS II AND III

SKIN ULCERATION

Perineural invasion is not identified.

(E) RIGHT NECK DISSECTION, LEVEL II "B":

METASTATIC SQUAMOUS CARCINOMA TWO OUT OF FIVE LYMPH NODES INVOLVED BY (2/5)

SOFT TISSUE TUMOR DEPOSIT WITH DENSE FIBROSIS.

Perineural invasion is not identified.

(F) NO TISSUE SUBMITTED

(G) LEFT LATERAL PHARYNX:

Squamous mucosa, negative for carcinoma.

(H) POSTERIOR CRICOID:

Squamous mucosa, negative for carcinoma.

(I) RIGHT LATERAL PHARYNX:

Squamous mucosa, negative for carcinoma.

(J) BASE OF TONGUE:

Benign squamous mucosa, negative for dysplasia or carcinoma; one benign lymph node (0/1).

(K) TOTAL LARYNGECTOMY AND RIGHT THYROIDECTOMY:

INVASIVE SQUAMOUS CARCINOMA -- Moderately differentiated

Tumor Features:

Gross: Exophytic

Size: 4.5 cm in largest dimension

Invasion: Present, depth 2.5 cm

Tumor Border: Infiltrative with thick cords > 4 cells

[page 2 of 3]
(K) TOTAL LARYNGECTOMY AND RIGHT THYROIDECTOMY (CONTINUED):

Perineural Invasion: Absent

Vascular Invasion: Absent

Bone / Cartilage Invasion: Cartilage invasion Present

Thyroid, negative for tumor.

GROSS DESCRIPTION

(A) LEFT NECK DISSECTION LEVEL II - Fibroadipose tissue (2.0 x 2.0 x 1.0 cm). Multiple lymph nodes are identified ranging from 0.1 x 0.1 x 0.1 cm to 1.5 x 1.0 x 0.7 cm.

SECTION CODE: A1-A3, each subcutaneous three lymph nodes; A4, one lymph node, serially sectioned.

(B) LEFT NECK DISSECTION LEVEL III - Fibroadipose tissue (2.0 x 2.0 x 1.3 cm). Eleven lymph nodes are identified ranging from 0.1 x 0.1 x 0.1 cm to 1.8 x 0.8 x 0.6 cm.

SECTION CODE: B1, four possible lymph nodes; B2, five lymph nodes; B3, one lymph node, bisected; B4, one lymph node, serially sectioned.

(C) LEFT NECK DISSECTION LEVEL IV - Fibroadipose tissue (4.0 x 4.0 x 1.8 cm). Multiple lymph nodes are identified ranging from 0.1 x 0.1 x 0.1 to 1.2 x 0.8 x 0.6 cm.

SECTION CODE: C1-C4, each containing four possible lymph nodes; C5, three lymph nodes; C6, three lymph nodes.

(D) RIGHT RADICAL NECK DISSECTION, LONG STITCH SUPERIOR ANTERIOR LEVEL II, SHORT STITCH POSTERIOR LEVEL V - A 9.0 x 8.0 x 3.1 cm portion of fibroadipose and muscular tissue that is partly surfaced by a 4.2 x 4.0 cm irregular portion of dark brown wrinkled skin. Located on the surface of the skin are two defects that 1.5 x 0.6 cm and 2.4 x 2.3 cm. The specimen is oriented by the surgeon with a long stitch designating superior anterior level II and a short stitch designating posterior level V. The specimen is divided into levels and dissected.

Level I - three possible lymph nodes ranging from 1.0 x 0.8 x 0.5 cm - 1.8 x 0.9 x 0.4 cm.

Level II - three possible lymph nodes ranging from 0.7 x 0.6 x 0.4 cm - 4.0 x 1.5 x 1.3 cm. The largest two possible lymph nodes are grossly positive with firm white and yellow cut surfaces.

Level III - three grossly positive lymph nodes ranging from 2.3 x 1.5 x 0.6 cm - 3.0 x 1.7 x 1.5 cm. The second largest is possibly a matted lymph node.

Level IV - three possible lymph nodes ranging from 0.7 x 0.5 x 0.3 cm - 1.5 x 1.1 x 0.6 cm.

Level V - one possible lymph node that measures 0.6 x 0.5 x 0.3 cm.

SECTION CODE: D1-D4, level I: D1, one possible lymph node serially sectioned; D2, one possible lymph node serially sectioned; D3, D4, one possible lymph node serially sectioned; D5-D10, level II: D5, one possible lymph node bisected; D6, D7, representative sections of one grossly positive lymph node serially sectioned; D8-D10, representative sections of one grossly positive lymph node serially sectioned, including skin; D11-D16, level III: D11, representative sections of smallest grossly positive lymph node serially sectioned; D12-D14, representative sections of matted grossly positive lymph node serially sectioned; D15, D16, representative sections of largest grossly positive lymph node serially sectioned; D17-D19, level IV: D17, one possible lymph node bisected; D18, one possible lymph node bisected; D19, one possible lymph node serially sectioned; D20, level V: D20, one possible lymph node serially sectioned.

[page 3 of 3]
(E) RIGHT NECK DISSECTION LEVEL II B - A piece of tan-brown soft tissue (4.5 x 2.0 x 1.5 cm) containing five possible lymph nodes ranging in size from 0.5 cm in greatest dimension to 1.4 x 0.7 x 0.5 cm. The largest lymph node is grossly suspicious for tumor involvement. There is a portion of dense, fibrous tissue (2.5 x 1.8 x 0.5 cm).

SECTION CODE: E1, largest lymph node (four pieces); E2, four possible lymph nodes; E3-E5, dense fibrous tissue.

(F) NO TISSUE SUBMITTED.

(G) LEFT LATERAL PHARYNX, INK AT TRUE MARGIN - A fragment of tan-pink soft tissue measuring 1.1 x 1.0 x 0.5 cm. Submitted for frozen section in toto.

SECTION CODE: G1, the entire specimen for frozen section.

*FS/DX: NEGATIVE.

(H) POSTERIOR CRICOID, INK AT TRUE MARGIN - A strip of tan-pink soft tissue measuring 1.8 x 0.8 x 0.8 cm. Submitted for frozen section in toto.

SECTION CODE: H, the entire specimen for frozen section.

*FS/DX: NEGATIVE.

(I) RIGHT LATERAL PHARYNX, INK AT TRUE MARGIN - tan-pink soft tissue, 1.5 x 0.5 x 0.5 cm submitted for frozen in I.

*FS/DX: NEGATIVE.

(J) BASE OF TONGUE, INK AT TRUE MARGIN - tan-pink soft tissue, 1.0 x 0.5 x 0.5 cm. Submitted for frozen in toto.

*FS/DX: MILD DYSPLASIA, CARCINOMA NOT IDENTIFIED.

(K) TOTAL LARYNGECTOMY AND RIGHT THYROIDECTOMY - A larynx including surrounding soft tissue and right thyroid lobe (8.5 cm in length x 6.5 cm in width x 4.5 cm anteroposterior, overall). The right thyroid lobe measures 4.5 x 2.0 cm.

A transglottic, ill-defined, raised tumor (4.5 x 2.0 cm with a depth of 2.5 cm) involving the right and left true vocal cords and extending to the supraglottic area, to vallecula. The tumor involves the thyroid cartilage and cricoid, but does not extend into the right thyroid lobe. Below the vocal cords the mucosa is nodular, with no evidence of invasion. These papulations extend near the tracheostomy site. The tracheostomy site and the tracheal resection margin are grossly uninvolved by tumor.

SECTION CODE: K1, thyroid; K2-K18, contains sequential sections of the tumor from right to left and superior to inferior as follows: K2-K4, tumor sections; K5, supraglottic; K6, infraglottic; K7, supraglottic; K8, glottic to infraglottic; K9, supraglottic, full thickness; K10, transglottic; K11, infraglottic; K12, supraglottic; K13, transglottic; K14, infraglottic; K15, supraglottic; K16, transglottic; K17, infraglottic; K18, additional section of tumor.

CLINICAL HISTORY

Squamous carcinoma of the larynx

SNOMED CODES

T-24100, M-80703

M-80703, "Some tests reported here may have been developed and performance characteristics determined by [redacted] Pathology and Laboratory Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by: [redacted]

Source: NCI Genomic Data Commons file 0e18c819-7d0e-4097-9e2d-cecd21c38ac8 (TCGA-CV-5978.F12E7021-3322-44BA-85E0-97E9A9199FB6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).